Gene-level copy-number profile of tumor specimen TARGET-40-PARBGW-01A from TARGET case TARGET-40-PARBGW, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.7 years (4,634 days).
Specimen TARGET-40-PARBGW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.f457f69c-019a-54b8-9852-1ebcb288caa0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PARBGW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/4e3654ee-3030-4eb1-b1f2-7f82de15e252

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 13,140; copy number 2: 44,622; copy number 3: 931; copy number 4: 224; copy number 5: 250; copy number 6: 95; copy number 7: 65; copy number 8: 96; copy number 9: 68; copy number 10: 71; copy number 11: 26; copy number 12: 18; copy number 13: 5; copy number 14: 12; copy number 15: 58; copy number 16: 33; copy number 17: 4; copy number 18: 6; copy number 19: 2; copy number 21: 9.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,645,902–116,723,581, 3 genes: BZW1P2, TUSC7, AC108713.1.
- chr8:3,700,492–4,329,027, 2 genes: RNA5SP251, AC027251.1.
- chr10:126,905,409–127,741,183, 7 genes (within-gene range 0–3): DOCK1, AL359094.1, AL359094.2, INSYN2A, NPS, AL391005.1, FOXI2.
- chr22:28,459,869–28,459,948, 1 gene: MIR5739.
- chr22:30,635,781–30,674,134, 4 genes (within-gene range 0–1): SLC35E4, DUSP18, AC003072.1, AC003072.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 818 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:124,962,545–126,258,355, 15 genes, copy number 9: RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr6:126,340,115–126,348,875, 1 gene, copy number 9: CENPW.
- chr6:127,708,072–127,918,631, 2 genes, copy number 6–11 (within-gene range 1–11): THEMIS, MRPS17P5.
- chr6:128,500,527–128,639,653, 4 genes, copy number 15–17: AL034349.1, EEF1DP5, Y_RNA, AL080315.1.
- chr7:69,026,433–69,046,803, 1 gene, copy number 19: AC104688.1.
- chr8:72,357,728–72,470,972, 3 genes, copy number 5: RNA5SP271, AC124293.1, AC011131.1.
- chr8:72,618,722–72,661,470, 2 genes, copy number 5: HAUS1P3, AC013562.2.
- chr8:85,833,377–86,743,675, 20 genes, copy number 6 (within-gene range 2–6): AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10.
- chr8:98,904,603–104,256,094, 134 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr8:124,260,646–125,541,373, 29 genes, copy number 5–8: RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr8:126,556,323–127,419,050, 1 gene, copy number 8 (within-gene range 3–8): PCAT1.
- chr8:127,072,694–130,655,712, 51 genes, copy number 5–10: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr8:131,712,512–131,712,980, 1 gene, copy number 5: AC060788.1.
- chr8:135,859,369–137,092,183, 1 gene, copy number 8 (within-gene range 2–8): LINC02055.
- chr8:136,237,236–137,105,458, 2 genes, copy number 8: AC023781.1, RNU6-144P.
- chr12:57,591,174–59,789,855, 55 genes, copy number 5–19 (within-gene range 1–19): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2.
- chr12:86,599,578–86,838,998, 1 gene, copy number 17 (within-gene range 1–17): AC010196.1.
- chr15:36,341,739–36,471,016, 2 genes, copy number 15: AC087516.1, AC087516.2.
- chr15:37,253,879–37,491,103, 3 genes, copy number 12: AC087283.1, AC068875.1, AC016304.1.
- chr15:40,894,450–43,185,779, 84 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr15:43,692,886–45,448,761, 75 genes, copy number 5–10 (broad region; genes not listed).
- chr15:48,120,990–49,620,929, 39 genes, copy number 7–16 (within-gene range 4–16): SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1, AC084757.3, AC084757.4, CEP152, AC084757.1, AC084757.2, AC012379.1, AC012379.2, SHC4, EID1, AC091073.1, KRT8P24, SECISBP2L, Y_RNA, RN7SL577P, AC013452.2, COPS2, Y_RNA, GALK2, NDUFAF4P1, MIR4716, AC013452.1, RN7SL307P, FAM227B, AC022306.2, AC022306.3, AC022306.1, FGF7.
- chr15:50,182,196–52,295,804, 72 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:53,419,865–53,762,878, 3 genes, copy number 7–11 (within-gene range 2–11): AC066614.1, WDR72, RNU2-53P.
- chr15:55,355,248–55,498,360, 1 gene, copy number 11 (within-gene range 3–11): DNAAF4-CCPG1.
- chr15:55,408,495–55,746,767, 8 genes, copy number 11–13: C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1, AC009997.1.
- chr15:62,390,526–64,381,440, 35 genes, copy number 5–15 (within-gene range 1–15): TLN2, MGC15885, AC100839.1, MIR190A, AC103740.1, AC103740.2, AC079328.1, TPM1, TPM1-AS, AC079328.2, AC087612.1, LACTB, RPS27L, RAB8B, APH1B, CA12, LINC02568, AC007950.1, AC007950.2, USP3, USP3-AS1, FBXL22, HERC1, AC073167.1, MIR422A, AC015914.2, DAPK2, AC015914.1, CIAO2A, SNX1, Y_RNA, SNX22, PPIB, CSNK1G1, AC087632.2.
- chr15:68,930,504–71,783,383, 53 genes, copy number 12–21 (within-gene range 1–21): AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2, GLCE, AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2, DRAIC, AC100826.1, GEMIN8P1, AC021818.1, TLE3, MIR629, RNU6-745P, AC026583.1, AC048383.1, LINC02205, AC009434.1, LINC02204, AC087699.1, SALRNA3, SALRNA2, UACA, AC009269.2, AC009269.5, AC009269.3, AC009269.1, RPL29P30, LARP6, AC009269.4, LRRC49, KRT8P9, THAP10, RPL5P3, THSD4, CT62, THSD4-AS1, HMGB1P6, AC064799.2, AC064799.1, AC108861.1.
- chr15:81,303,215–83,207,823, 64 genes, copy number 5 (broad region; genes not listed).
- chr15:83,654,088–84,039,842, 1 gene, copy number 6 (within-gene range 1–6): ADAMTSL3.
- chr15:83,824,863–84,945,798, 48 genes, copy number 6: RNU6-1339P, AC027807.2, AC027807.1, EFL1P1, DNM1P41, AC136698.1, UBE2Q2L, CSPG4P11, GOLGA2P7, RN7SL331P, GOLGA6L4, UBE2Q2P8, AC243562.2, RN7SL417P, AC243562.1, DNM1P51, CSPG4P5, UBE2Q2P11, AC243562.3, Metazoa_SRP, UBE2Q2P12, AC048382.4, AC048382.3, GOLGA6L5P, AC048382.2, UBE2Q2P1, LINC00933, AC048382.5, ZSCAN2, AC048382.1, AC048382.6, SCAND2P, EGLN1P1, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, AC012291.3, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1.
- chr15:85,579,046–85,580,178, 1 gene, copy number 7: AC087286.3.
- chr15:85,621,264–85,627,689, 1 gene, copy number 7: AC087286.1.
- chr15:86,630,266–86,631,136, 1 gene, copy number 18: AC012229.1.
- chr15:86,938,797–87,047,303, 2 genes, copy number 6 (within-gene range 4–6): AC016987.1, AC078905.1.
- chr15:87,638,688–88,256,768, 2 genes, copy number 5–7 (within-gene range 3–7): AC103871.1, NTRK3.

Autosomal genes at a single copy (total copy number 1): 10,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
